Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A3LS, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A3LS-01A (Primary Tumor).

[page 1 of 3]
Patient:

Physician:

CC:

Patient Address:

Date of Receipt:

Date of Report:

....

Clinical Diagnosis & History:

Specimens Submitted:

1: Radical resection of left upper retroperitoneal mass, splenectomy left adenopathy left kidney

DIAGNOSIS:

1. Left kidney, left adrenal, spleen, portion of stomach, retroperitoneal mass; radical resection with partial gastrectomy, splenectomy, left adrenalectomy and left nephrectomy:
- Dedifferentiated Liposarcoma.
- Size - 13.2 x 10.5 x 7.5cm; three separate tumor nodules are also present, measuring 3.2, 3.0 and 2.0 cm respectively.
- The dedifferentiated component is predominantly a high-grade spindle cell sarcoma and focally shows a divergent rhabdomyosarcomatous differentiation. (see Note)
- Tumor necrosis is grossly estimated at 20%.
- The tumor involves the spleen, envelops around the kidney and adrenal and extends upto the stomach.
- The well-differentiated liposarcoma component extends to the deep margin; all other margins are uninvolved.

NOTE: The tumor is predominantly composed of streaming fascicles of spindle cells with moderate to severe cytologic atypia. Focal areas with a rhabdoid morphology are identified. The mitotic rate is 13 per 50 high power fields. In the spindled areas, the tumor is positive for SMA (in a myofibroblastic pattern) and negative for desmin. In the more rhabdoid areas, there is myogenin and desmin positivity, confirming a divergent rhabdomyosarcomatous differentiation.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

** Continued on next page **

18B-0-3
dedifferentiated liposarcoma 8858/3
Site: retroperitoneum C48.0

hw
12/23/11

[page 2 of 3]
Gross Description:

1. The specimen is received fresh, labeled "partial gastrectomy, radical resection of retroperitoneal left upper quadrant mass, splenectomy, left adrenalectomy, left kidney," and consists of a 1700g, 24 x 15 x 9cm radical resection oriented as per requisition. There is a well-demarcated, white-pink fleshy retroperitoneal tumor (T) with 20% geographic necrosis (13.2 x 10.5 x 7.5cm), situated between the spleen and stomach, and superior to the adrenal gland and kidney. There may be a softer, slightly yellow area (? well-differentiated component, 30%) at the superior aspect of the specimen. The mass has the following relationships with the margin: deep (black) 0.4cm; anterior (peritoneum; yellow) 0.2cm; superior (blue) 0.2cm; inferior (red) 4.5cm; lateral (green) 0.2cm; medial (orange) 1.5cm. The tumor is adjacent and adherent to the spleen, stomach, kidney and adrenals; it appears to invade the spleen. It appears distinct from the surrounding adipose tissue, without any apparent areas of transition.

Three separate pink firm nodules of tumor are also identified, (N1, 3.2 x 2.8 x 1.7cm; N2, 3.0 x 2.0 x 2.0cm; N3, 2.0 x 1.5cm). The smallest nodule appears to invade the spleen. They are all far from the inked margins.

The spleen (14 x 10 x 4cm) has a smooth capsule and red cut surface, with gross preservation of white and red pulp. No additional lesions are identified. The portion of stomach (4 x 2.5cm) shows somewhat flattened folds but is otherwise without gross abnormalities. The kidney (13 x 7 x 3.5cm) has a preserved cortex (0.8cm) and smooth surface underneath the capsule. Its associated ureter is 6.0cm long and 0.3 cm in diameter; the vascular margins are grossly unremarkable. The adrenal (3.0 x 1.0 x 0.6cm) has a somewhat thinned cortex, but is otherwise unremarkable.

Photographs are taken. Representative tissue is submitted for _____ and permanent sections.

Summary of sections:

SM - superior margin and tumor
IM - inferior margin
LM - lateral margin
MM - medial margin
AM - anterior margin
DM - deep margin and tumor
KT - kidney and relationship with tumor
KVM - representative normal kidney with vascular margins and ureteric margin
ST - spleen and relationship with tumor
S - representative normal spleen.
AT - adrenal and tumor
A - representative normal adrenal
STT - stomach and tumor
ST - representative normal stomach
T - additional representative sections of tumor
N1 - nodule 1
N2 - nodule 2
N3 - nodule 3 (with spleen)

** Continued on next page **

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

Patient:

Accession #:

Page 3 of 3

Summary of Sections:

Part 1: Radical resection of left upper retroperitoneal mass, splenectomy
left adenopathy left kidney

Block	Sect.	Site	PCs
1	A		1
1	AM		1
1	AT		1
1	DM		1
1	IM		1
1	KT		1
1	KVM		1
1	LM		1
1	MM		1
2	N1		2
1	N2		1
1	N3		1
2	S		2
1	SM		1
3	ST		3
10	T		10

** End of Report **

Source: NCI Genomic Data Commons file 7256e33a-0518-4a20-adcb-3154ee4a8ec0 (TCGA-DX-A3LS.097D95F9-C5CD-4688-B3B9-6F9C61BE69A8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).